CCDI case PBCGUB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/22454b81-d7a5-4813-91e1-aa21c746be07

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 12.0 years (4,396 days).

Biospecimens (3 samples)
- Sample 0DRKKF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRKKM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRKKY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
